Somatic mutation profile of tumor specimen TCGA-A6-6651-01A (aliquot TCGA-A6-6651-01A-21D-1835-10) from TCGA case TCGA-A6-6651, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 55.1 years (20,110 days).
Specimen TCGA-A6-6651-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ba7219e-be47-4eb2-b9c4-bc7f29b40e62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6651-10A (Blood Derived Normal), aliquot TCGA-A6-6651-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/765e75f2-3759-46bf-b046-f10828e487ed

The open-access MAF lists 92 somatic variants for this specimen: 68 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 23, Frame Shift Del 3, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 38/91 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC018630.4 | c.158A>C p.Q53P | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV57392588; called by muse, mutect2
- ADAMTS20 | c.5099C>T p.A1700V | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); catalogued as rs1402234102, COSV67137497; called by muse, mutect2, varscan2
- ADGRL3 | c.1306G>C p.D436H (on ENST00000506720 / NM_001322402.2; = p.D368H on NM_015236.6) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72272307; called by muse, mutect2, varscan2
- ANK2 | c.10266G>T p.E3422D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.21); catalogued as rs1240304125, COSV52183078; called by muse, mutect2, varscan2
- ANKS6 | c.1780G>T p.A594S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV62051776; called by muse, mutect2, varscan2
- C12orf66 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100320625; called by muse, mutect2
- CATSPERD | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.619); catalogued as rs757541319, COSV58464623; called by muse, mutect2, varscan2
- CDHR2 | c.1361C>T p.T454I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs762901848, COSV56139109, COSV56143919; called by muse, mutect2, varscan2
- CLCN2 | c.2369T>C p.I790T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV55603603; called by muse, mutect2, varscan2
- COL12A1 | c.6598G>C p.G2200R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100485643; called by muse, mutect2, varscan2
- DGKD | c.1805T>A p.I602K (on ENST00000264057 / NM_152879.3; = p.I558K on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV51089955; called by muse, mutect2, varscan2
- DNAH7 | c.3920C>T p.T1307M | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs766596492, COSV56780925; called by muse, mutect2, varscan2
- DST | c.11967_11968del p.R3989Sfs*17 (on ENST00000361203 / NM_001374722.1; = p.R1577Sfs*17 on NM_015548.5) | Frame Shift Del (DEL) | VAF 25/97 reads (26%) | catalogued as rs767199911; called by pindel, varscan2
- EPHB2 | c.2414C>T p.S805L (on ENST00000400191 / NM_001309193.2; = p.S806L on NM_004442.7) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1281028518, COSV65859706; called by muse, mutect2
- FIGN | c.1654G>A p.G552S | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs755526237, COSV60763767, COSV60766070; called by muse, mutect2, varscan2
- FUBP1 | c.1874A>G p.Y625C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs762248194, COSV53937005; called by muse, mutect2, varscan2
- FYB1 | c.972dup p.P325Afs*43 | Frame Shift Ins (INS) | VAF 32/156 reads (21%) | catalogued as rs748874978; called by mutect2, varscan2
- GJC1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs776242102, COSV57912516; called by muse, mutect2, varscan2
- GPRC5B | c.194C>A p.A65E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100315003; called by muse, mutect2, varscan2
- HTR5A | c.920T>A p.I307N | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV55284786, COSV99839543; called by muse, mutect2, varscan2
- ITPKC | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1334311279, COSV54574502; called by muse, mutect2
- KCNN2 | c.1670G>A p.R557Q (on ENST00000264773; = p.R769Q on NM_021614.4) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.921); catalogued as rs772419723, COSV53294015; called by muse, mutect2, varscan2
- KIF21A | c.3455A>T p.K1152M (on ENST00000361418 / NM_001378440.1; = p.K1139M on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV62773908, COSV62776773; called by muse, varscan2
- KRT37 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs369082535; called by muse, mutect2, varscan2
- LRP1B | c.12938C>T p.P4313L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs759893587, COSV101254409, COSV67280348; called by muse, mutect2, varscan2
- LRRIQ3 | c.1075T>C p.Y359H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV63048832; called by muse, mutect2, varscan2
- LYPLAL1 | c.65C>A p.A22D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV100859680; called by muse, mutect2, varscan2
- MPPED2 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.945); catalogued as COSV63900685; called by muse, mutect2, varscan2
- MTMR6 | c.1545A>G p.I515M | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV67809447; called by muse, mutect2, varscan2
- MTOR | c.2088G>T p.L696F | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63877024; called by muse, mutect2, varscan2
- NEU4 | c.367C>T p.R123C (on ENST00000391969 / NM_001167602.3; = p.R135C on NM_080741.4) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs370244576; called by muse, mutect2, varscan2
- NFATC1 | c.1946A>T p.D649V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV53707664, COSV99500211; called by muse, mutect2, varscan2
- NLRP7 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as rs748418867, COSV60180471; called by muse, mutect2, varscan2
- NRG1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as COSV55155703, COSV55172943; called by muse, varscan2
- OR2A12 | c.421A>G p.T141A | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV68821873; called by muse, mutect2, varscan2
- PCDHB8 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 16/536 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as COSV50753684; called by muse, mutect2
- PDC | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60854739; called by muse, mutect2, varscan2
- PINK1 | c.1352A>C p.N451T | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM065378, COSV58632601; called by muse, mutect2, varscan2
- POTEM | c.261C>A p.D87E | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV69152257; called by muse, mutect2
- PRKRA | c.446A>G p.Q149R | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as COSV57870318; called by muse, mutect2
- PUS1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371146708, COSV59036363; called by muse, mutect2, varscan2
- RBP3 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs781844060; called by muse, mutect2, varscan2
- REST | c.1416T>A p.D472E | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.411); catalogued as COSV58362359; called by muse, mutect2, varscan2
- RFC4 | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV56218307; called by muse, mutect2, varscan2
- RIN1 | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV60926153; called by muse, mutect2, varscan2
- RLIM | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.996); catalogued as COSV60328669; called by muse, mutect2
- ROBO1 | c.2361T>A p.N787K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.18); catalogued as COSV71397767; called by muse, mutect2, varscan2
- SERPINI2 | c.72A>C p.Q24H | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.606); catalogued as COSV52988425; called by mutect2, varscan2
- SLC16A5 | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1568010867, COSV99822592; called by muse, mutect2, varscan2
- SLC4A4 | c.1157A>G p.D386G (on ENST00000264485 / NM_001098484.3; = p.D342G on NM_003759.4) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52635074; called by muse, mutect2, varscan2
- SLITRK5 | c.443C>A p.T148N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs146758652, COSV61523854; called by mutect2, varscan2
- SMO | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV50839414; called by muse, mutect2, varscan2
- SPATA31D1 | c.4628C>G p.P1543R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); catalogued as COSV61200157; called by muse, mutect2
- STX19 | c.116T>G p.V39G | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV100115241, COSV57400936; called by muse, mutect2, varscan2
- TAAR9 | c.898G>T p.V300F | Missense Mutation (SNP) | VAF 70/330 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV101453319; called by muse, mutect2, varscan2
- TCF20 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV59494165, COSV59495270; called by muse, mutect2, varscan2
- TIGD2 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs994139106, COSV57648595; called by muse, mutect2, varscan2
- TSEN2 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV53189466, COSV53190565; called by muse, mutect2, varscan2
- VPS13B | c.2215G>A p.G739S | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100661357; called by muse, mutect2
- ZMAT4 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52711504; called by muse, mutect2, varscan2
- ZNF709 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.91); catalogued as COSV101172114; called by muse, varscan2
- ZNF711 | c.2014A>G p.K672E | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV52158058; called by muse, mutect2, varscan2
- ADGRV1 | c.11418del p.G3807Dfs*10 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.1360del p.V454Ffs*24 | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | called by mutect2, pindel, varscan2
- PPP1R3A | c.1678dup p.R560Kfs*46 | Frame Shift Ins (INS) | VAF 22/163 reads (13%) | called by mutect2, pindel, varscan2
- RYR3 | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- VPS8 | c.3091C>A p.Q1031K (on ENST00000625842 / NM_001349294.1; = p.Q1029K on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ABCB6 | c.114T>G p.A38= | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as COSV54699370; called by muse, mutect2, varscan2
- AFF2 | c.198A>G p.A66= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV100649482; called by muse, mutect2
- CHST1 | c.711C>T p.R237= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV57325233; called by muse, mutect2, varscan2
- CSMD2 | c.7698C>T p.G2566= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs771706014, COSV53936624; called by mutect2, varscan2
- ENTPD6 | c.1059C>T p.H353= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs375550123, COSV61751872; called by muse, mutect2, varscan2
- FAIM2 | c.621C>G p.L207= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as rs375275250; called by muse, mutect2, varscan2
- FLRT2 | c.1599G>A p.T533= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV58144895; called by muse, mutect2, varscan2
- GPR6 | c.294G>A p.A98= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV51570896; called by muse, mutect2
- HAPLN4 | c.396C>T p.N132= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs372359274; called by muse, mutect2
- IDE | c.726G>A p.L242= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV56426531; called by muse, mutect2, varscan2
- KCNS3 | c.867C>G p.V289= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV58408588; called by muse, mutect2, varscan2
- KRT10 | c.330C>A p.G110= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV54091163; called by mutect2, varscan2
- LRRN2 | c.1911C>T p.L637= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs777988442, COSV65783867; called by muse, mutect2, varscan2
- NLRP7 | c.1698C>T p.T566= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs760124890, COSV60180464; called by muse, mutect2, varscan2
- NRP2 | c.2127G>A p.L709= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV55934223; called by muse, mutect2, varscan2
- PCDHA11 | c.2145G>T p.L715= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV56477321, COSV56537919; called by muse, mutect2, varscan2
- SENP5 | c.948G>A p.V316= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100051896; called by muse, mutect2, varscan2
- SLC2A14 | c.1113G>T p.T371= | Silent (SNP) | VAF 33/313 reads (11%) | catalogued as rs755253436, COSV100533683, COSV100534119; called by muse, mutect2, varscan2
- SMOC1 | c.417C>T p.V139= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV62762970; called by muse, mutect2, varscan2
- SPRED1 | c.966G>A p.K322= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs1374483645, COSV54438486; called by muse, mutect2, varscan2
- UBR4 | c.6324C>G p.G2108= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100920627; called by mutect2, varscan2
- ZNF512B | c.2082G>A p.L694= | Silent (SNP) | VAF 51/95 reads (54%) | catalogued as rs1403387983, COSV53877165; called by muse, mutect2, varscan2
- ZNF516 | c.1560C>T p.C520= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV71587535; called by muse, mutect2, varscan2
- RPL26P30 | n.612C>T | RNA (SNP) | VAF 9/37 reads (24%) | catalogued as rs1370515374; called by muse, mutect2, varscan2
